Gene-level copy-number profile of tumor specimen TCGA-D8-A1JJ-01A from TCGA case TCGA-D8-A1JJ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.7 years (19,966 days).
Specimen TCGA-D8-A1JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.d52157a2-cf02-470c-b912-78697cb75086.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a9591dc9-b423-46c4-b247-9ea7699ced1f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,419; copy number 2: 10,689; copy number 3: 14,376; copy number 4: 20,185; copy number 5: 5,515; copy number 6: 6,598; copy number 7: 719; copy number 8: 88; copy number 9: 110; copy number 10: 89; copy number 31: 6; copy number 44: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JJ-01A-31D-A14J-01): tumor purity 0.43, ploidy 3.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 227 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:14,489,107–15,341,368, 22 genes, copy number 44: GRIP2, RNU6-905P, RHBDF1P1, AC090952.2, AC090952.1, CCDC174, C3orf20, AC090957.1, AC087591.1, LINC02011, FGD5, FGD5-AS1, NR2C2, MRPS25, RBSN, AC090954.1, RPS3AP53, COL6A4P1, CAPN7, SH3BP5-AS1, SH3BP5, RNU6-454P.
- chr3:75,664,330–75,785,583, 5 genes, copy number 31: FRG2C, DUX4L26, LINC00960, ZNF717, MIR4273.
- chr3:75,964,980–75,965,069, 1 gene, copy number 31: Y_RNA.
- chr3:80,163,327–80,217,234, 2 genes, copy number 9: OSBPL9P1, HNRNPA3P8.
- chr7:23,710,203–24,694,193, 11 genes, copy number 9 (within-gene range 6–9): STK31, PCMTD1P3, TPT1P7, AC003087.1, RNA5SP228, AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14.
- chr8:78,148,101–83,408,900, 92 genes, copy number 9–10 (broad region; genes not listed).
- chr8:86,866,415–94,104,322, 88 genes, copy number 9–10 (broad region; genes not listed).
- chr8:95,204,456–95,811,254, 1 gene, copy number 9 (within-gene range 7–9): C8orf37-AS1.
- chr8:95,244,913–95,527,524, 3 genes, copy number 9: C8orf37, AC024995.1, AC083836.1.
- chr10:9,275,833–9,309,772, 2 genes, copy number 9: LINC00709, AL138773.1.

Autosomal genes at a single copy (total copy number 1): 1,419. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
